BEATAML1.0 case 2443 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/88f18be3-16f9-470b-b7a8-85f5919eda9f

Biospecimens (1 sample)
- Sample BA2686R: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
